Somatic mutation profile of tumor specimen TCGA-VS-A9UQ-01A (aliquot TCGA-VS-A9UQ-01A-21D-A42O-09) from TCGA case TCGA-VS-A9UQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 32.5 years (11,853 days).
Specimen TCGA-VS-A9UQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f55187e-8412-4e1a-bacd-caf24818a1a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UQ-10A (Blood Derived Normal), aliquot TCGA-VS-A9UQ-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ad34dd4-1cf3-4b61-8164-775dac67577b

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.308T>A p.I103N | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs730880502, COSV61072424; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 59/234 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1996A>G p.K666E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754688962, COSV59206172, COSV59206856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AL592490.1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs781402479, COSV101308111; called by muse, mutect2, varscan2
- ATP2C2 | c.1949C>A p.T650N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV99297478; called by muse, mutect2, varscan2
- CACNA1A | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV100801010, COSV100803275; called by muse, mutect2, varscan2
- CPSF2 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as COSV100102537; called by muse, mutect2, varscan2
- ERICH3 | c.4484C>G p.A1495G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100443444; called by muse, mutect2, varscan2
- FBN1 | c.5782T>C p.C1928R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM055247, CM950448, COSV100354058; called by muse, mutect2, varscan2
- GRK6 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867783337, COSV100586834; called by muse, mutect2
- H6PD | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as COSV101072419; called by muse, mutect2
- KMT2D | c.7157G>A p.R2386Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs763262491, COSV99977716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MORC1 | c.1976C>A p.A659D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV51733316, COSV99225144; called by muse, mutect2, varscan2
- NAA25 | c.853G>C p.A285P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.602); catalogued as COSV99927281; called by muse, mutect2, varscan2
- NFKBIZ | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100396919; called by muse, mutect2, varscan2
- PLXNA3 | c.5367G>T p.E1789D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100859813; called by muse, mutect2, varscan2
- SEPTIN4 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.197); catalogued as rs773605152, COSV58727061; called by muse, mutect2, varscan2
- WDR7 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs746338942, COSV99588610; called by muse, mutect2, varscan2
- ZEB2 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100355034; called by muse, mutect2, varscan2
- SLC5A5 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TTC27 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- BSN | c.2412C>T p.D804= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs544564146, COSV99607338; called by muse, mutect2, varscan2
- CENPI | c.27C>T p.N9= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs1434404391, COSV99515038; called by muse, mutect2, varscan2
- UBE2Q1 | c.903C>T p.N301= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs752589979, COSV52727742; called by muse, mutect2, varscan2
- ZNF43 | c.1242T>A p.T414= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100731693; called by muse, mutect2
